Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GG-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate/poor differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: gastro-esophageal junction

Tumor size: diameter 4,5 cm

Lymph node status: 19 lymph nodes, of which 4 contains tumor

Any comments or amendments: irradical resection

ICD-O-3
Adenocarcinoma NOS 8140/3
Site ^{CDF} Esophagus, distal third C15.5
path Gastroesophageal junction C16.0
JW 1/29/14

Source: NCI Genomic Data Commons file d6cf5a5d-b98e-4c53-8aed-a5e966c06ffb (TCGA-2H-A9GG.1092CAAD-DAA6-4008-A1F5-597F3B1B453E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).